Surgical pathology report (de-identified scan), TCGA case TCGA-29-1710, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1710-02A (Recurrent Tumor).

[REDACTED]

Surg Path

CLINICAL HISTORY:

Malignant neoplasm ovary

GROSS EXAMINATION:

A. "Liver tumor nodule", received fresh and placed in formalin is a 1.4 x 1 x 0.7 cm fragment of pink-tan tissue submitted in toto in block A1.

[REDACTED]

1CD-0-3

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

Carcinoma, NOS, metastatic 8010/6

Site: liver c22.0

DIAGNOSIS:

A. "LIVER TUMOR NODULE" (BIOPSY):

fw
2/12/15

METASTATIC CARCINOMA CONSISTENT WITH OVARIAN PRIMARY.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 7d886c68-2531-48eb-bb76-e7ca048d2a14 (TCGA-29-1710.4FD493D6-DAA8-497E-8EB2-ED2A97034B23.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).